Surgical pathology report (de-identified scan), TCGA case TCGA-08-0357, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0357-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

TCGA-08-0357

FINAL PATHOLOGIC DIAGNOSIS

Brain, left temporoparietal region, biopsy and resection: Glioblastoma multiforme.

Intraoperative Diagnosis

FS1 (A) Brain, left temporoparietal region, biopsy: Glioblastoma multiforme. Tissue section and cytologic preparation. [REDACTED]

Gross Description

The specimen is received in six parts, each labeled with the patient's name and medical record number.

Part A is received fresh and is additionally labeled "tumor FS." It consists of two fragments of very soft, red-yellow tissue, measuring 0.6 x 0.5 x 0.2 cm in aggregate. The specimen is entirely submitted for frozen section diagnosis as FS1, with the frozen section remnant submitted in cassette A1.

Part B, labeled [REDACTED] and cross-referenced as [REDACTED] consists of multiple soft, irregular pieces of red tissue measuring 0.3 x 0.2 x 0.1 cm in aggregate. The specimen is entirely submitted in cassette B1.

Part C, labeled [REDACTED] and cross-referenced as [REDACTED] consists of multiple soft, irregular pieces of red tissue measuring 0.3 x 0.2 x 0.1 cm in aggregate. The specimen is entirely submitted in cassette C1.

Part D, labeled [REDACTED] and cross-referenced as [REDACTED] consists of multiple soft, irregular pieces of red tissue measuring 0.4 x 0.2 x 0.1 cm in aggregate. The specimen is entirely submitted in cassette D1.

Part E, labeled [REDACTED] and cross-referenced as [REDACTED] consists of multiple soft, irregular pieces of red tissue measuring 0.5 x 0.2 x 0.1 cm in aggregate. The specimen is entirely submitted in cassette E1.

Part F is received fresh in a sealed plastic suction cannister and is additionally labeled "#2 CUSA contents." It consists of an abundant amount of soft, irregular, highly fragmented and minced pieces of pink-tan tissue, measuring 4.5 x 3.0 x 1.0 cm in aggregate. Representative sections are submitted in cassettes F1

[page 2 of 2]
through F8.

Clinical History

The patient is a [REDACTED] with an enhancing left temporoparietal lesion. He undergoes biopsy to rule out glioblastoma.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

ADDENDUM

Addendum Diagnosis

Brain, biopsy:

Immunohistochemical study was performed as per request of [REDACTED]

The immunohistochemical analysis show that the neoplastic cells are negative for antibodies against EGFR.

Source: NCI Genomic Data Commons file 6d2f1371-1fab-4cd3-ba43-39487eb83c8f (TCGA-08-0357.ADCB7011-4301-4D17-AC6D-21773386E307.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).